Gene-level copy-number profile of tumor specimen ALCH-ADUO-TTP1-A from ALCHEMIST case ALCH-ADUO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.0 years (23,360 days).
Specimen ALCH-ADUO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dbfea5d9-7603-4651-8c5b-e65398d33d8c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADUO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/0df30b33-7c86-4c6e-98d3-eb0a4733459c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 18,538; copy number 2: 37,172; copy number 3: 2,478; copy number 4: 85; copy number 6: 46; copy number 7: 4; copy number 10: 4; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:10,896,045–11,201,833, 8 genes (within-gene range 0–1): XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2, AF131215.1.
- chr9:21,367,424–23,956,444, 45 genes: IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3.
- chr9:29,824,742–31,254,777, 12 genes: ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2.
- chr9:136,796,338–136,810,042, 2 genes (within-gene range 0–2): CCDC183, AL355987.4.
- chr9:136,803,927–136,808,848, 1 gene (within-gene range 0–1): CCDC183-AS1.
- chr10:49,679,651–49,710,261, 1 gene: C10orf53.
- chr10:49,771,841–49,773,299, 1 gene: MAPK6P6.
- chr13:19,152,567–19,181,824, 3 genes: SMPD4P2, AL139327.3, TUBA3C.
- chr16:87,693,537–87,696,147, 1 gene (within-gene range 0–1): AC010536.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 55 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,542,325–56,080,670, 46 genes, copy number 6 (within-gene range 3–6): VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2.
- chr9:136,744,017–136,748,525, 2 genes, copy number 10 (within-gene range 2–10): LCN6, MIR6722.
- chr11:112,967–139,612, 3 genes, copy number 10–11 (within-gene range 2–11): AC069287.1, CICP23, LINC01001.
- chr21:43,414,483–43,479,534, 4 genes, copy number 7: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 18,538. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
